Gene-level copy-number profile of tumor specimen TARGET-10-PATCKV-09A from TARGET case TARGET-10-PATCKV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,266 days).
Specimen TARGET-10-PATCKV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.5c9c4bfb-b1eb-502b-bcae-782e99a46577.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATCKV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate.
https://portal.gdc.cancer.gov/files/34758830-46d1-437a-868f-4c3301a9ae45

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,509; copy number 2: 48,456; copy number 3: 9,189; copy number 4: 116.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 128. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
